Somatic mutation profile of tumor specimen ALCH-B3ZT-TTP1-A (aliquot ALCH-B3ZT-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,814 days).
Specimen ALCH-B3ZT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff5d979a-7532-47cf-9b2e-93b7eb9228f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZT-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZT-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43c2d54b-f088-4a24-a686-b90aa366d2ba

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 8, Frame Shift Del 2, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM135B | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 9/252 reads (4%) | catalogued as COSV50526390; called by muse, mutect2
- NCSTN | c.2048C>A p.S683Y | Missense Mutation (SNP) | VAF 85/855 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54188345; called by muse, mutect2
- SLCO2A1 | c.1248C>A p.F416L | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV100189175; called by muse, mutect2
- TGFBR2 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 52/1135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55444129; called by muse, mutect2
- TPCN1 | c.1820A>G p.Y607C | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1474607239; called by muse, mutect2
- TRPM3 | c.4909G>A p.E1637K (on ENST00000357533 / NM_001366142.2; = p.E1492K on NM_020952.6) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100678544; called by muse, mutect2
- IGLON5 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRDM15 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 54/729 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- RETREG3 | c.1367_1376del p.S456Tfs*42 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SPTA1 | c.2239A>G p.T747A | Missense Mutation (SNP) | VAF 22/533 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.042); called by muse, mutect2
- TMEM200C | c.1528del p.L510Cfs*45 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- ASXL2 | c.4197A>G p.K1399= | Silent (SNP) | VAF 22/438 reads (5%) | called by muse, mutect2
- BPTF | c.7341C>G p.S2447= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- CPM | c.1311T>C p.L437= | Silent (SNP) | VAF 294/397 reads (74%) | called by muse, mutect2, varscan2
- LAMA3 | c.9441G>A p.V3147= (on ENST00000313654 / NM_198129.4; = p.V1538= on NM_000227.6) | Silent (SNP) | VAF 60/1114 reads (5%) | called by muse, mutect2
- MAPK4 | c.447C>T p.D149= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- NT5C1B | c.1065C>T p.F355= (on ENST00000359846 / NM_001199086.2; = p.F295= on NM_033253.4) | Silent (SNP) | VAF 38/956 reads (4%) | catalogued as COSV58394300; called by muse, mutect2
- OR5P2 | c.465T>C p.Y155= | Silent (SNP) | VAF 24/384 reads (6%) | catalogued as COSV61490854; called by muse, mutect2
- USF3 | c.4356C>T p.H1452= | Silent (SNP) | VAF 34/634 reads (5%) | called by muse, mutect2
- HGF | c.-22C>T | 5'UTR (SNP) | VAF 24/701 reads (3%) | called by muse, mutect2
- TSPYL2 | c.997+31T>C | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as rs1459990293; called by muse, mutect2, varscan2
